Somatic mutation profile of tumor specimen ALCH-B20K-TTP1-A (aliquot ALCH-B20K-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B20K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 75.1 years (27,440 days).
Specimen ALCH-B20K-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 367bed1e-bbeb-404c-afd6-9df451085d2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B20K-NB1-A (Blood Derived Normal), aliquot ALCH-B20K-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e0d4013-c128-4514-9046-5ed64502a159

The open-access MAF lists 116 somatic variants for this specimen: 76 protein-altering or splice-affecting, 24 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 24, Intron 6, RNA 3, Splice Site 3, 5'UTR 3, 3'UTR 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV53351928; called by muse, mutect2, varscan2
- CCDC158 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs764577428, COSV66357241; called by muse, mutect2
- COL11A1 | c.3955C>A p.P1319T | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV62185922; called by muse, mutect2
- CSMD2 | c.5236A>T p.R1746W | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378736116; called by muse, mutect2
- DNAAF1 | c.1566C>A p.F522L | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV57578558; called by muse, mutect2
- DPEP2 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1420998100; called by muse, mutect2
- DPP10 | c.1490G>T p.R497M | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV59705415; called by muse, mutect2
- DPP10 | c.1491G>T p.R497S | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs201256183, COSV59708051; called by muse, mutect2
- EGFLAM | c.829-1G>T p.X277_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100379752, COSV59294262; called by mutect2, varscan2
- HGF | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1490588192; called by muse, mutect2
- KHDRBS2 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99832027; called by muse, mutect2
- LRRTM4 | c.973T>A p.W325R | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV69141833; called by muse, mutect2
- MTFR1 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs779292997; called by muse, mutect2
- MUC16 | c.5012C>T p.S1671F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV101201640; called by muse, mutect2, varscan2
- OR11H12 | c.12G>C p.L4F | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV101612517; called by mutect2, varscan2
- OR4N2 | c.900G>T p.K300N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV60049957; called by mutect2, varscan2
- PCDHGA2 | c.381C>G p.N127K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53917444, COSV99544762; called by muse, mutect2, varscan2
- PDHA2 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV54778340; called by muse, mutect2, varscan2
- PLEKHS1 | c.149G>C p.S50T (on ENST00000369310 / NM_182601.1; = p.S56T on NM_024889.5) | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.209); catalogued as COSV63054311; called by muse, mutect2
- PRRC2C | c.3496A>G p.T1166A (on ENST00000367742; = p.T1164A on NM_015172.4) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs763749671; called by muse, mutect2
- PSG3 | c.615T>G p.F205L | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs187697889; called by muse, mutect2, varscan2
- RXRB | c.976G>C p.G326R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.346); catalogued as COSV59494735; called by muse, mutect2, varscan2
- SPEG | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs542443881, COSV56676102; called by muse, mutect2, varscan2
- TYK2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs200247986, COSV99315724; called by muse, mutect2
- UBXN2B | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367929276; called by muse, mutect2
- WDR90 | c.3038del p.P1013Qfs*98 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs752097396; called by pindel, varscan2
- ADCY2 | c.2870A>T p.Q957L | Missense Mutation (SNP) | VAF 9/257 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2
- APBB1IP | c.411A>T p.L137F | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2
- ARHGEF10 | c.1930T>C p.S644P (on ENST00000398564; = p.S619P on NM_014629.4) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2
- C16orf78 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2orf78 | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHRNA1 | c.530T>C p.V177A (on ENST00000261007 / NM_001039523.3; = p.V152A on NM_000079.4) | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL17A1 | c.3351T>G p.S1117R | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2
- COL1A2 | c.4041G>C p.L1347F | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2
- CORIN | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DCD | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX31 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- DLGAP1 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 46/535 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- DMRT3 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.3477G>C p.Q1159H | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FBXW12 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2
- FOXL2NB | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 23/412 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- GPR139 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRIN3A | c.3049T>C p.S1017P | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ICA1 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- IGSF9B | c.623G>C p.C208S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNS1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- KMO | c.361+1G>T p.X121_splice | Splice Site (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- MBOAT4 | c.1114T>G p.W372G | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.199); called by muse, mutect2
- NIM1K | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- NRCAM | c.3223G>T p.A1075S | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.01); called by muse, mutect2
- PAK3 | c.1625G>T p.S542I (on ENST00000262836 / NM_001324328.2; = p.S527I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- PCDHA8 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PDZD7 | c.2437C>A p.H813N | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.617); called by muse, mutect2
- PIEZO2 | c.5711A>C p.Q1904P | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); called by muse, mutect2
- PIK3CG | c.2321T>G p.L774R | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKD2L2 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2
- RELN | c.7583G>C p.S2528T | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.017); called by muse, mutect2
- RELN | c.3305C>A p.S1102Y | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- SDR16C5 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 11/373 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB10 | c.299T>A p.L100H | Missense Mutation (SNP) | VAF 17/359 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- SLC22A24 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SOX30 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 29/445 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2
- SPATS1 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 57/414 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST8SIA2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 35/508 reads (7%) | PolyPhen benign (0.031); called by muse, mutect2
- SYCP2L | c.1303A>T p.R435* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- SYNPO2 | c.1865A>G p.Y622C | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- TAF4B | c.1528C>G p.Q510E | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); called by muse, mutect2
- TENM3 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM225 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TNXB | c.3440C>A p.P1147H | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTN | c.43517T>G p.V14506G (on ENST00000591111; = p.V7082G on NM_003319.4) | Missense Mutation (SNP) | VAF 16/396 reads (4%) | PolyPhen probably damaging (0.948); called by muse, mutect2
- TTN | c.33809G>T p.G11270V (on ENST00000591111; = p.G10343V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/436 reads (5%) | PolyPhen benign (0.246); called by muse, mutect2
- TTN | c.33809-1G>T p.X11270_splice (on ENST00000591111; = p.X10343_splice on NM_133378.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 20/438 reads (5%) | called by muse, mutect2
- UGT1A1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDFY4 | c.8070G>T p.E2690D | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BPIFB3 | c.774C>T p.I258= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV64957106, COSV64957858; called by muse, mutect2
- BRPF1 | c.1977G>T p.L659= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs766222212; called by muse, mutect2, varscan2
- BTBD17 | c.420A>G p.R140= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- CAMK2A | c.837C>T p.S279= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- CDK5RAP2 | c.3564G>T p.P1188= | Silent (SNP) | VAF 26/246 reads (11%) | catalogued as rs545235391; called by muse, mutect2
- COL2A1 | c.3306A>C p.P1102= | Silent (SNP) | VAF 36/252 reads (14%) | called by muse, mutect2, varscan2
- EPB41L3 | c.273A>T p.S91= | Silent (SNP) | VAF 31/431 reads (7%) | catalogued as rs376036017; called by muse, mutect2
- GBA3 | c.354C>A p.L118= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- H3C13 | c.328C>T p.L110= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as rs782447573; called by muse, mutect2
- HRC | c.1113T>C p.H371= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV99418124; called by muse, mutect2
- KCNH5 | c.786C>T p.I262= | Silent (SNP) | VAF 50/263 reads (19%) | catalogued as COSV59761198, COSV59768519; called by muse, mutect2, varscan2
- LDB2 | c.345C>A p.S115= | Silent (SNP) | VAF 18/281 reads (6%) | catalogued as COSV58763679; called by muse, mutect2
- MUC16 | c.8055C>A p.T2685= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs575464012; called by muse, mutect2, varscan2
- MXRA5 | c.7731C>A p.V2577= | Silent (SNP) | VAF 19/217 reads (9%) | called by muse, mutect2
- PCARE | c.2994G>A p.R998= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, varscan2
- PCDHGA2 | c.1347A>G p.A449= | Silent (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- PFKM | c.54C>T p.R18= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- RBM15 | c.2649T>C p.S883= | Silent (SNP) | VAF 6/149 reads (4%) | called by muse, mutect2
- SKIL | c.456A>G p.E152= | Silent (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- SLC6A6 | c.534G>A p.K178= | Silent (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2
- TINAG | c.711A>G p.Q237= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- USP15 | c.2836C>A p.R946= (on ENST00000280377 / NM_001351159.2; = p.R917= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 21/299 reads (7%) | called by muse, mutect2
- ZFHX4 | c.4938C>A p.G1646= | Silent (SNP) | VAF 17/195 reads (9%) | catalogued as COSV50519796; called by muse, mutect2
- ZNF141 | c.1389C>T p.F463= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs145502841; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848709 T>C | 5'Flank (SNP) | VAF 8/226 reads (4%) | called by muse, mutect2
- ASAP1 | c.186+17122G>C | Intron (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- CALCR | c.-5C>A | 5'UTR (SNP) | VAF 22/302 reads (7%) | catalogued as rs1442769420, COSV64005734, COSV64006320, COSV64011384; called by muse, mutect2
- COL22A1 | c.*55C>A | 3'UTR (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- CPLANE1 | c.*726G>T | 3'UTR (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- CRTAP | c.-15C>T | 5'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- HSPA7 | n.262G>C | RNA (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- MBNL2 | c.805-658G>A | Intron (SNP) | VAF 8/219 reads (4%) | catalogued as COSV59119623; called by muse, mutect2
- MIR196A1 | n.34G>T | RNA (SNP) | VAF 14/261 reads (5%) | called by muse, mutect2
- MIR513C | n.31T>C | RNA (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- NUDT7 | c.190-347C>T | Intron (SNP) | VAF 8/108 reads (7%) | catalogued as rs1210346437; called by muse, mutect2
- PLEKHG4B | c.1419+91A>T | Intron (SNP) | VAF 17/130 reads (13%) | called by muse, varscan2
- RCN1 | c.689-238A>G | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SNRPN | chr15:24982080 C>A | 3'Flank (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- TMEM30A | c.-60C>T | 5'UTR (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- TPI1 | c.227-514G>T | Intron (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
